Gene-level copy-number profile of tumor specimen TCGA-FS-A1Z0-06A from TCGA case TCGA-FS-A1Z0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.2 years (17,255 days).
Specimen TCGA-FS-A1Z0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7747d210-d47f-40ee-af86-9bfe73d5b0c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1Z0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4cdd1cb1-19ce-4c38-a88f-5d523d713e02

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 16,129; copy number 2: 35,251; copy number 3: 4,916; copy number 4: 1,585; copy number 5: 1,908; copy number 6: 8; copy number 7: 4; copy number 10: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1Z0-06A-11D-A191-01): tumor purity 0.73, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:165,905,126–166,926,370, 5 genes: AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947.
- chr6:100,508,194–100,881,372, 1 gene (within-gene range 0–1): ASCC3.
- chr6:100,881,471–100,890,338, 2 genes: AL133338.1, AL133338.2.
- chr9:21,994,139–22,128,103, 5 genes (within-gene range 0–2): CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,922 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–66,728,904, 1,570 genes, copy number 5 (broad region; genes not listed).
- chr6:68,223,667–68,635,161, 5 genes, copy number 5: AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr6:69,866,556–74,850,484, 83 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr6:84,421,028–87,721,018, 64 genes, copy number 5 (broad region; genes not listed).
- chr6:89,254,464–89,352,722, 3 genes, copy number 5: GABRR2, TUBB3P1, UBE2J1.
- chr6:96,521,595–98,948,006, 22 genes, copy number 5 (within-gene range 1–5): UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4.
- chr6:101,181,257–102,070,083, 1 gene, copy number 5 (within-gene range 0–5): GRIK2.
- chr6:102,078,872–104,859,919, 12 genes, copy number 5 (within-gene range 1–5): AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P.
- chr6:107,028,199–107,459,564, 6 genes, copy number 5 (within-gene range 1–5): MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr6:109,440,724–109,506,800, 4 genes, copy number 7: SMPD2, MICAL1, ZBTB24, AL109947.1.
- chr6:111,900,305–112,254,939, 8 genes, copy number 6 (within-gene range 1–6): LINC02527, CCN6, TUBE1, FAM229B, LAMA4, Z99289.1, RNU6-1226P, Z99289.2.
- chr6:118,894,152–119,349,761, 9 genes, copy number 5 (within-gene range 1–5): ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P.
- chr6:120,462,511–121,858,768, 20 genes, copy number 5: AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18.
- chr6:125,119,049–125,302,078, 3 genes, copy number 5: TPD52L1, HDDC2, AL121938.1.
- chr6:127,118,671–129,861,547, 38 genes, copy number 5: RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244.
- chr6:133,821,147–134,121,433, 8 genes, copy number 5–10: LINC01312, TCF21, TBPL1, AL035699.1, SLC2A12, AL449363.1, AL449363.2, HMGA1P7.
- chr6:135,991,936–136,225,751, 1 gene, copy number 5 (within-gene range 1–5): AL138828.1.
- chr6:136,206,478–136,289,851, 3 genes, copy number 5: AL138828.2, MTFR2, BCLAF1.
- chr6:146,598,967–146,815,462, 4 genes, copy number 5 (within-gene range 1–5): ADGB, AL359547.2, RNU6-906P, KATNBL1P6.
- chr6:147,508,690–147,737,547, 1 gene, copy number 5 (within-gene range 1–5): SAMD5.
- chr6:148,272,304–148,552,048, 1 gene, copy number 5 (within-gene range 1–5): SASH1.
- chr6:148,478,693–148,567,654, 2 genes, copy number 5: CYP51A1P3, SNRPEP6.
- chr6:150,061,053–150,326,763, 4 genes, copy number 5: ULBP3, PPP1R14C, AL355497.3, RNU4-7P.
- chr6:151,494,017–152,637,801, 10 genes, copy number 5 (within-gene range 1–5): CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223.
- chr6:154,733,378–155,257,723, 7 genes, copy number 5 (within-gene range 1–5): SCAF8, RNU6-824P, TIAM2, AL121952.1, MIR1273C, U8, AL136228.1.
- chr6:158,650,014–159,170,007, 17 genes, copy number 5 (within-gene range 1–5): SYTL3, AMZ2P2, MIR3918, EZR, EZR-AS1, OSTCP1, AL627422.2, C6orf99, AL627422.1, RNU6-293P, RSPH3, AL035530.2, TAGAP, AL035530.1, AL356417.3, AL356417.1, AL356417.2.
- chr6:159,353,922–159,798,436, 16 genes, copy number 5: AL357832.1, LINC02529, AL078604.4, AL078604.1, AL078604.3, AL078604.2, SOD2, HNRNPH1P1, RNU4ATAC18P, WTAP, SOD2-OT1, ACAT2, TCP1, SNORA20, SNORA29, MRPL18.

Autosomal genes at a single copy (total copy number 1): 16,129. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
